Somatic mutation profile of tumor specimen MMRF_2279_1_BM_CD138pos (aliquot MMRF_2279_1_BM_CD138pos_T1_KHS5U_K14062) from MMRF case MMRF_2279, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,813 days).
Specimen MMRF_2279_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0de61d2e-702a-4958-8f09-ecb67dbca71d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2279_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2279_2_PB_Whole_C1_KHS5U_K15188; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d867bd6-4e26-467f-a5ac-c5ebb4a4574f

The open-access MAF lists 91 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 18, Intron 13, Silent 8, RNA 3, Splice Region 3, 3'Flank 3, 5'Flank 2, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs750824318, COSV58158834; called by muse, mutect2, varscan2
- ARHGAP39 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1396473798; called by muse, mutect2, varscan2
- HPX | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1322376835, COSV56419390; called by muse, mutect2
- MYH10 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52597878; called by muse, mutect2, varscan2
- PLPPR4 | c.539-4A>G | Splice Region (SNP) | VAF 19/52 reads (37%) | catalogued as rs763136544; called by mutect2, varscan2
- PPP3R2 | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62451814; called by muse, mutect2
- PRDM15 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs772692177; called by muse, mutect2, varscan2
- SH3BP4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.216); catalogued as rs770776091; called by muse, mutect2, varscan2
- SYNM | c.2965G>T p.V989F | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1227249011; called by muse, mutect2
- ALPP | c.195G>A p.G65= | Splice Region (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- C8orf34 | c.327+8G>A | Splice Region (SNP) | VAF 15/316 reads (5%) | called by muse, mutect2
- CANT1 | c.1117_1125del p.Y373_M375del | In Frame Del (DEL) | VAF 29/75 reads (39%) | called by mutect2, pindel, varscan2
- CTNNBL1 | c.200_205del p.G67_E68del | In Frame Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- CWC22 | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DAAM2 | c.2012C>A p.S671* | Nonsense Mutation (SNP) | VAF 46/67 reads (69%) | called by muse, mutect2, varscan2
- ETV2 | c.953A>T p.Y318F | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MAPK8 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- OR4C6 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PAGR1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PHF20L1 | c.256-1G>A p.X86_splice | Splice Site (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- PLCZ1 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- RGMB | c.236del p.S79Lfs*38 (on ENST00000513185 / NM_001366508.1; = p.S120Lfs*38 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/182 reads (21%) | called by mutect2, pindel, varscan2
- RNF213 | c.14204_14232del p.V4735Efs*6 | Frame Shift Del (DEL) | VAF 8/111 reads (7%) | called by mutect2, pindel
- SNX30 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TAOK3 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPSD1 | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC28 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF121 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ARF6 | c.87C>T p.I29= | Silent (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- FIBCD1 | c.870C>T p.D290= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs773144212, COSV99446653; called by muse, mutect2, varscan2
- LAMA1 | c.5820C>T p.N1940= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs368850544; called by muse, mutect2, varscan2
- MRPL53 | c.306C>T p.S102= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- MUC16 | c.16308A>T p.S5436= | Silent (SNP) | VAF 48/246 reads (20%) | called by muse, mutect2, varscan2
- SALL3 | c.1614C>T p.H538= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs773279214, COSV73305996; called by muse, mutect2, varscan2
- SERPINA7 | c.376C>T p.L126= | Silent (SNP) | VAF 60/61 reads (98%) | catalogued as rs754443066; called by muse, mutect2, varscan2
- SLITRK5 | c.102C>T p.V34= | Silent (SNP) | VAF 10/274 reads (4%) | catalogued as COSV100281081, COSV61525892; called by muse, mutect2
- AL645728.2 | n.108A>C | RNA (SNP) | VAF 24/51 reads (47%) | catalogued as rs1557442863; called by muse, mutect2, varscan2
- ALDH6A1 | c.*1382C>T | 3'UTR (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
- C14orf132 | chr14:96091164 C>A | 3'Flank (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- C17orf107 | chr17:4899439 C>G | 5'Flank (SNP) | VAF 20/34 reads (59%) | called by muse, varscan2
- CACNA1C | c.4956+74del | Intron (DEL) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- CACNA2D2 | chr3:50503608 C>G | 5'Flank (SNP) | VAF 8/12 reads (67%) | catalogued as rs867581167; called by muse, mutect2, varscan2
- CACUL1 | c.*1433dup | 3'UTR (INS) | VAF 11/53 reads (21%) | catalogued as rs775284880; called by mutect2, pindel, varscan2
- CCDC171 | c.*775G>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | catalogued as COSV66239988; called by muse, mutect2, varscan2
- CCDC187 | c.*3118C>G | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- CCDC187 | c.*3000C>T | 3'UTR (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- CCDC187 | c.*2841C>G | 3'UTR (SNP) | VAF 29/110 reads (26%) | called by muse, varscan2
- CCDC187 | c.*2491C>G | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, varscan2
- CCDC187 | c.*2455C>T | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, varscan2
- CCDC9B | chr15:40332789 C>T | 3'Flank (SNP) | VAF 26/126 reads (21%) | catalogued as rs1305879977; called by muse, varscan2
- CD36 | c.1254+108T>G | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- CDC37L1 | c.*1628_*1630del | 3'UTR (DEL) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- CENPH | c.*220T>G | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- DCC | c.*901C>A | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- DMRT3 | c.*482G>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- DNAJB8 | c.-189C>T | 5'UTR (SNP) | VAF 30/60 reads (50%) | catalogued as rs1009574696; called by muse, mutect2, varscan2
- EGLN1 | c.*1831A>G | 3'UTR (SNP) | VAF 50/83 reads (60%) | catalogued as rs895690491; called by muse, mutect2, varscan2
- ETV2 | c.*3A>T | 3'UTR (SNP) | VAF 116/234 reads (50%) | called by muse, varscan2
- FGF14 | c.*7103A>G | 3'UTR (SNP) | VAF 87/193 reads (45%) | catalogued as COSV101087732; called by muse, mutect2, varscan2
- FILIP1 | c.*403A>C | 3'UTR (SNP) | VAF 15/16 reads (94%) | called by muse, mutect2, varscan2
- GPR35 | c.-149+170C>T | Intron (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.632+1838T>C | Intron (SNP) | VAF 46/149 reads (31%) | called by muse, mutect2, varscan2
- ISCU | c.*420A>C | 3'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*2441A>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- LRRC7 | c.1545+45T>C | Intron (SNP) | VAF 42/96 reads (44%) | catalogued as rs773718961; called by muse, mutect2, varscan2
- LSM1 | c.46+162C>T | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, varscan2
- MCF2 | c.*199A>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- MYO1G | c.2745+45C>T | Intron (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- NRIP1 | c.*1694G>A | 3'UTR (SNP) | VAF 41/82 reads (50%) | catalogued as rs996339174, COSV59660512; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156504 A>T | 3'Flank (SNP) | VAF 232/389 reads (60%) | called by muse, mutect2, varscan2
- PITPNM3 | c.*2794T>C | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3700-48_3700-42del | Intron (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- PNPLA8 | c.*631del | 3'UTR (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.*2564T>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- PPP1R32 | c.1044-122C>A | Intron (SNP) | VAF 27/79 reads (34%) | catalogued as rs1410578125; called by muse, mutect2, varscan2
- PTCHD1 | c.*2624C>T | 3'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- PTGR1 | c.209+201dup | Intron (INS) | VAF 171/363 reads (47%) | catalogued as rs1402180918; called by mutect2, pindel, varscan2
- REG3G | c.*134C>T | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.240-55T>C | Intron (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2
- RUFY3 | c.*511A>G | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- SIKE1 | c.*427T>C | 3'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- SLC23A2 | c.483-71A>C | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SV2C | c.-31C>T | 5'UTR (SNP) | VAF 9/227 reads (4%) | catalogued as rs1561229208, COSV100456782; called by muse, mutect2
- TAF4B | c.1832+1782A>G | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- TAFA1 | c.*74T>G | 3'UTR (SNP) | VAF 56/137 reads (41%) | called by muse, varscan2
- TAFA1 | c.*160C>A | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, varscan2
- TCAF1P1 | n.152dup | RNA (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- TRIM77BP | n.489C>T | RNA (SNP) | VAF 19/71 reads (27%) | catalogued as rs1306253639; called by muse, mutect2, varscan2
- TXNDC5 | c.*699C>T | 3'UTR (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- ZNF197 | c.*2449A>T | 3'UTR (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ZNF648 | c.*250G>A | 3'UTR (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
